Somatic mutation profile of tumor specimen TCGA-66-2786-01A (aliquot TCGA-66-2786-01A-01W-0877-08) from TCGA case TCGA-66-2786, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.6 years (25,051 days).
Specimen TCGA-66-2786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7ce7942-fb52-4745-9c4f-f98eb76155d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2786-11A (Solid Tissue Normal), aliquot TCGA-66-2786-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bee1f2d-7400-4f1b-ae81-deaedf907a49

The open-access MAF lists 206 somatic variants for this specimen: 162 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 42, Nonsense Mutation 12, Frame Shift Del 8, Splice Site 7, Splice Region 2, Frame Shift Ins 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSB | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 101/311 reads (32%) | catalogued as rs891298440, CM003996, COSV53728737; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TF | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918681, CM043106, COSV53925152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 64/159 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- ABCC12 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV60919324; called by muse, mutect2, varscan2
- ABL1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV59326084, COSV59334718; called by muse, mutect2
- ACSL3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62485212; called by mutect2, varscan2
- ADAMTS12 | c.4752G>T p.R1584S | Missense Mutation (SNP) | VAF 55/732 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100710020, COSV61283962; called by muse, mutect2
- AGBL1 | c.2337G>T p.M779I | Missense Mutation (SNP) | VAF 168/628 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV66877470; called by muse, mutect2, varscan2
- ANO5 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61082265, COSV61091301; called by muse, mutect2, varscan2
- APOC3 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV57139062; called by muse, mutect2, varscan2
- ATP1A3 | c.2044G>A p.D682N (on ENST00000545399 / NM_001256214.2; = p.D669N on NM_152296.5) | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV57491969; called by muse, mutect2, varscan2
- ATP2B3 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848929; called by muse, mutect2, varscan2
- ATRX | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV64875734, COSV64885839; called by muse, mutect2
- BCAR3 | c.2397G>C p.E799D | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53080305; called by muse, mutect2, varscan2
- BCOR | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60713743, COSV60721284; called by muse, mutect2, varscan2
- BCORL1 | c.4965G>T p.E1655D | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54409774; called by muse, mutect2, varscan2
- CA5B | c.585A>T p.K195N | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV59418102; called by muse, mutect2
- CADM3 | c.640G>C p.E214Q (on ENST00000368125 / NM_001127173.3; = p.E248Q on NM_021189.5) | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); catalogued as COSV63686422, COSV63687908; called by muse, mutect2, varscan2
- CADPS2 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390367; called by muse, mutect2, varscan2
- CCNB3 | c.4072T>C p.Y1358H | Missense Mutation (SNP) | VAF 232/777 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV52081180; called by muse, mutect2, varscan2
- CD200R1L | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68005103; called by muse, mutect2, varscan2
- CDH10 | c.1987G>T p.G663* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | catalogued as COSV52578640, COSV52581433; called by muse, mutect2, varscan2
- CDH10 | c.672C>G p.N224K | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52602340; called by muse, mutect2, varscan2
- CDH12 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66457550; called by muse, mutect2
- CHD6 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV64689337; called by muse, mutect2, varscan2
- CHD8 | c.4648G>A p.D1550N (on ENST00000646647 / NM_001170629.2; = p.D1271N on NM_020920.4) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV63219535, COSV63219851; called by muse, mutect2, varscan2
- CHORDC1 | c.563+1G>T p.X188_splice | Splice Site (SNP) | VAF 39/113 reads (35%) | catalogued as COSV57707218; called by muse, mutect2, varscan2
- CHRM3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99698771; called by muse, mutect2
- CHRNB4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777719189, COSV55718787; called by muse, mutect2, varscan2
- CLEC9A | c.400T>A p.W134R | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63351899; called by muse, mutect2
- CLIC2 | c.583-1G>A p.X195_splice | Splice Site (SNP) | VAF 31/164 reads (19%) | catalogued as COSV100425644; called by muse, mutect2, varscan2
- CLSTN2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 50/484 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71725810; called by muse, mutect2, varscan2
- CLSTN2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71725811; called by muse, mutect2, varscan2
- CLVS2 | c.881C>G p.P294R | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV51570063; called by muse, mutect2, varscan2
- CMTR2 | c.683C>G p.T228S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs376567812; called by muse, mutect2
- CNTN6 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs990536728, COSV63193421; called by muse, mutect2, varscan2
- COL22A1 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 51/218 reads (23%) | catalogued as COSV57365795; called by muse, mutect2, varscan2
- COL6A6 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV62040375; called by muse, mutect2, varscan2
- CPS1 | c.3463G>T p.A1155S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51827793; called by muse, mutect2
- CSMD3 | c.5744C>T p.A1915V (on ENST00000297405 / NM_001363185.1; = p.A1811V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs553075730, COSV52350462; called by muse, mutect2, varscan2
- CSTF2 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV65895407; called by muse, mutect2, varscan2
- CTAGE1 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV66943234, COSV66945393; called by muse, mutect2
- CX3CR1 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 122/331 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV64195665; called by muse, mutect2, varscan2
- DCAF12L2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV63584639; called by muse, mutect2, varscan2
- DGKB | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826779; called by muse, mutect2, varscan2
- DST | c.5620T>C p.S1874P | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99757871; called by muse, mutect2, varscan2
- DUS2 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as COSV62710166; called by muse, mutect2, varscan2
- ENTHD1 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1204556425, COSV57326263; called by muse, mutect2, varscan2
- EXD2 | c.1333A>T p.I445F (on ENST00000312994 / NM_001193362.1; = p.I320F on NM_018199.3) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.582); catalogued as COSV57282790; called by muse, mutect2, varscan2
- FAM209A | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV54769575; called by muse, mutect2, varscan2
- FARP2 | c.2788-1G>A p.X930_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV50885809; called by mutect2, varscan2
- FAT4 | c.14792A>G p.N4931S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58713956; called by muse, mutect2, varscan2
- FBXL2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV52143682; called by muse, mutect2, varscan2
- FBXO4 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs369814713; called by muse, mutect2, varscan2
- FMR1 | c.1361G>C p.R454P | Missense Mutation (SNP) | VAF 96/441 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54426577, COSV54428337; called by muse, mutect2, varscan2
- GALK2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59106249; called by muse, mutect2, varscan2
- GCM1 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV52521497, COSV52523211; called by muse, varscan2
- GDAP1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55187639, COSV99619246; called by muse, mutect2
- GGT5 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.387); catalogued as COSV54070722, COSV54073048; called by muse, mutect2, varscan2
- GOLGA3 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs763136916, COSV52645512, COSV52646595; called by muse, mutect2, varscan2
- GPRIN3 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV60886775; called by muse, mutect2, varscan2
- GSE1 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs367594478; called by muse, mutect2
- GYG2 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58552115; called by muse, mutect2, varscan2
- GYG2 | c.954dup p.P319Afs*14 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs770047512; called by mutect2, varscan2
- HAS1 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55790297; called by muse, mutect2, varscan2
- HLTF | c.2173G>T p.A725S | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV59504221; called by muse, mutect2, varscan2
- HMCN1 | c.10574-1G>A p.X3525_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | catalogued as COSV54950326; called by muse, mutect2, varscan2
- HOOK2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53404619; called by muse, mutect2, varscan2
- HOXC10 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV57727314; called by muse, varscan2
- HS3ST4 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 107/403 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779140172, COSV58812234; called by muse, mutect2, varscan2
- IGHM | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs781884098; called by muse, mutect2, varscan2
- KANSL2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs554290180, COSV63480658; called by muse, mutect2, varscan2
- KMT2A | c.10115C>G p.T3372S | Missense Mutation (SNP) | VAF 59/676 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63293914; called by muse, mutect2
- KNG1 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53981748; called by muse, mutect2, varscan2
- LUZP1 | c.991A>C p.N331H | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56506286; called by muse, mutect2, varscan2
- MAGEB10 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV63313020; called by muse, mutect2, varscan2
- MFN1 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54943199; called by muse, mutect2, varscan2
- MIA2 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV54503162; called by muse, mutect2, varscan2
- MPDZ | c.4082G>T p.G1361V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225982249, COSV59926145; called by muse, mutect2, varscan2
- MYO10 | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV72563880; called by muse, mutect2, varscan2
- NEDD4 | c.2403+1G>A p.X801_splice (on ENST00000508342 / NM_001284338.1; = p.X382_splice on NM_006154.4) | Splice Site (SNP) | VAF 40/134 reads (30%) | catalogued as COSV59067710; called by muse, mutect2, varscan2
- NETO1 | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.991); catalogued as COSV55016993; called by muse, mutect2, varscan2
- NEURL4 | c.3130dup p.A1044Gfs*3 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs754613626; called by mutect2, pindel
- OR2M7 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs143090101, COSV58740084; called by muse, mutect2, varscan2
- OR4C46 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.292); catalogued as COSV100060364, COSV60221609; called by muse, mutect2, varscan2
- OR5R1 | c.77del p.P26Rfs*7 | Frame Shift Del (DEL) | VAF 37/188 reads (20%) | catalogued as rs1565136350; called by mutect2, pindel, varscan2
- PEG3 | c.1568A>T p.H523L | Missense Mutation (SNP) | VAF 35/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55651638; called by muse, mutect2
- PER1 | c.3224C>G p.S1075C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57922677; called by muse, mutect2, varscan2
- PER1 | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57922686; called by muse, mutect2, varscan2
- PIWIL1 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 44/514 reads (9%) | catalogued as rs1451658538, COSV55353107; called by muse, mutect2
- PKP4 | c.3458C>G p.S1153C | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV61580851; called by muse, mutect2, varscan2
- PNCK | c.492G>T p.Q164H (on ENST00000340888 / NM_001366975.1; = p.Q247H on NM_001039582.3) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61745854; called by muse, mutect2, varscan2
- PPFIA2 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61060273; called by muse, mutect2, varscan2
- PPFIA3 | c.3390G>T p.W1130C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53259454; called by muse, mutect2
- PPFIBP2 | c.2001C>T p.N667= | Splice Region (SNP) | VAF 90/262 reads (34%) | catalogued as rs755779633, COSV55083752; called by muse, mutect2
- PPP2R3A | c.2342A>T p.Q781L | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV53872265; called by muse, mutect2, varscan2
- PRB4 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.763); catalogued as rs574597591, COSV54400818; called by muse, mutect2, varscan2
- PRB4 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 393/1526 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV54400833; called by muse, mutect2, varscan2
- PRKD2 | c.1779C>A p.S593R | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV52190510; called by muse, mutect2, varscan2
- PRRG3 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV64851640; called by muse, mutect2, varscan2
- PTCH1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as CM054086, COSV59477446; called by muse, mutect2, varscan2
- PTPRT | c.3814G>T p.V1272L | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.304); catalogued as COSV100628535; called by mutect2, varscan2
- PWWP3B | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.71); catalogued as COSV61802018; called by muse, mutect2, varscan2
- RALGAPB | c.2563-1G>C p.X855_splice | Splice Site (SNP) | VAF 101/493 reads (20%) | catalogued as COSV53445852; called by muse, mutect2, varscan2
- RNF144A | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.261); catalogued as COSV57985991; called by muse, mutect2, varscan2
- RYR2 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63721094; called by muse, mutect2, varscan2
- RYR3 | c.9011T>C p.F3004S (on ENST00000389232; = p.F3005S on NM_001036.6) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66811646; called by muse, mutect2, varscan2
- SENP2 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56198768; called by muse, mutect2, varscan2
- SETD2 | c.5266G>T p.E1756* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV57447230, COSV57455108; called by muse, mutect2, varscan2
- SH3RF1 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52926211; called by muse, mutect2, varscan2
- SHPRH | c.4594C>G p.L1532V (on ENST00000275233 / NM_001042683.3; = p.L1536V on NM_173082.3) | Missense Mutation (SNP) | VAF 64/947 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1420032880, COSV51619605; called by muse, mutect2
- SIGLEC1 | c.3356A>G p.Y1119C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52475249; called by muse, mutect2
- SIK2 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59256812; called by muse, mutect2, varscan2
- SLC18A1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52351749; called by muse, mutect2, varscan2
- SLC22A8 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100267680, COSV60327617; called by muse, mutect2, varscan2
- SLC26A8 | c.943-1G>C p.X315_splice | Splice Site (SNP) | VAF 85/131 reads (65%) | catalogued as COSV62887411, COSV62888125; called by muse, mutect2, varscan2
- SLC6A18 | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57255138; called by muse, mutect2, varscan2
- SLITRK4 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 55/173 reads (32%) | catalogued as COSV62026672; called by muse, mutect2, varscan2
- STARD8 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52934135; called by muse, mutect2, varscan2
- STK11IP | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as COSV55257130; called by muse, mutect2
- SYNE1 | c.19366G>T p.D6456Y (on ENST00000367255 / NM_182961.4; = p.D6385Y on NM_033071.3) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55131300; called by muse, mutect2, varscan2
- SYNE1 | c.19365A>T p.E6455D (on ENST00000367255 / NM_182961.4; = p.E6384D on NM_033071.3) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV55131353; called by muse, mutect2, varscan2
- TBC1D25 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV65124896; called by muse, mutect2, varscan2
- TECTA | c.4418G>A p.R1473H | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV50837882; called by muse, mutect2, varscan2
- TFCP2L1 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV55295938; called by muse, mutect2, varscan2
- TICRR | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV51548444; called by muse, mutect2, varscan2
- TLE3 | c.2237G>C p.S746T | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58176092; called by muse, mutect2
- TMEM132B | c.1592T>C p.I531T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54774431; called by muse, mutect2, varscan2
- TMEM161A | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV50778337; called by muse, mutect2, varscan2
- TMX3 | c.390T>C p.S130= | Splice Region (SNP) | VAF 11/104 reads (11%) | catalogued as COSV55188551; called by muse, mutect2, varscan2
- TNN | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773607661, COSV53421649; called by mutect2, varscan2
- TNS3 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV60801269; called by muse, mutect2, varscan2
- TPM1 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV51268307; called by muse, mutect2, varscan2
- TRIM46 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866560615, COSV55279009, COSV55280426; called by muse, mutect2, varscan2
- TRIP12 | c.1842G>C p.Q614H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV52274385; called by muse, varscan2
- TRPV5 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143560130; called by muse, mutect2, varscan2
- TTN | c.89415G>C p.E29805D (on ENST00000591111; = p.E22381D on NM_003319.4) | Missense Mutation (SNP) | VAF 114/462 reads (25%) | PolyPhen probably damaging (0.99); catalogued as COSV60417495; called by muse, mutect2, varscan2
- TTN | c.59792T>C p.I19931T (on ENST00000591111; = p.I12507T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | PolyPhen benign (0.215); catalogued as rs765749707, COSV60243457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.38644G>A p.D12882N (on ENST00000591111; = p.D5458N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | PolyPhen possibly damaging (0.691); catalogued as COSV60417587; called by muse, mutect2, varscan2
- TTN | c.11408A>G p.Q3803R (on ENST00000591111; = p.Q3757R on NM_003319.4) | Missense Mutation (SNP) | VAF 67/279 reads (24%) | catalogued as COSV60417632; called by muse, mutect2, varscan2
- TUT7 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV52899734; called by muse, mutect2, varscan2
- TYRO3 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.74); catalogued as COSV55487936; called by muse, mutect2, varscan2
- TYW3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1172771294, COSV100904852, COSV63802869, COSV63803459; called by muse, mutect2, varscan2
- WDR3 | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV62525796; called by muse, mutect2
- WDR7 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 43/435 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.177); catalogued as COSV54365849; called by muse, mutect2, varscan2
- WDR72 | c.430T>A p.L144M | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64755063; called by muse, mutect2, varscan2
- WSCD2 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54592553, COSV99775068; called by muse, mutect2, varscan2
- ZDHHC5 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54709580, COSV54709754; called by muse, mutect2, varscan2
- ZNF407 | c.2606T>G p.I869S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55274653; called by muse, mutect2, varscan2
- ZNF569 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.878); catalogued as COSV57599994; called by muse, mutect2, varscan2
- ZNF586 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.31); catalogued as rs946422174, COSV66972466, COSV66972813; called by muse, mutect2, varscan2
- ABI3BP | c.548del p.N183Tfs*2 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- HRH4 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 62/597 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEB6B | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- METAP2 | c.1005del p.Q335Hfs*13 | Frame Shift Del (DEL) | VAF 62/211 reads (29%) | called by mutect2, pindel, varscan2
- PDS5A | c.3139del p.H1047Mfs*4 | Frame Shift Del (DEL) | VAF 43/141 reads (30%) | called by mutect2, pindel, varscan2
- POLR2A | c.3304A>G p.M1102V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAFB2 | c.1321_1324del p.N441Pfs*36 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by pindel, varscan2
- SPATA31A1 | c.368del p.P123Qfs*30 | Frame Shift Del (DEL) | VAF 105/289 reads (36%) | called by mutect2, pindel, varscan2
- TMEM131 | c.5252C>G p.S1751* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- VPS13C | c.1516_1519del p.D506Nfs*15 (on ENST00000644861 / NM_020821.3; = p.D463Nfs*15 on NM_017684.5) | Frame Shift Del (DEL) | VAF 75/300 reads (25%) | called by mutect2, pindel, varscan2
- ZNF516 | c.1703_1707del p.P568Qfs*10 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by pindel, varscan2
- ABCC10 | c.2340C>G p.L780= (on ENST00000372530 / NM_001198934.2; = p.L752= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV55095218; called by muse, mutect2
- ADAM32 | c.1185C>A p.G395= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs765460290, COSV65954146, COSV65954362; called by muse, mutect2, varscan2
- ADGRG2 | c.1167C>A p.S389= (on ENST00000379869 / NM_001079858.3; = p.S386= on NM_005756.4) | Silent (SNP) | VAF 90/351 reads (26%) | catalogued as COSV61341962; called by muse, mutect2, varscan2
- ANKS1B | c.3564A>T p.L1188= (on ENST00000547776 / NM_152788.4; = p.L354= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV59126206; called by muse, mutect2, varscan2
- ANO5 | c.213C>A p.I71= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV61091291; called by muse, mutect2, varscan2
- ATP2B3 | c.1989C>T p.N663= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs200802886, COSV54864791; called by muse, mutect2, varscan2
- BBX | c.1455C>T p.S485= | Silent (SNP) | VAF 41/482 reads (9%) | catalogued as rs200479657; called by muse, mutect2
- BDP1 | c.6753A>G p.P2251= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV62435865; called by muse, mutect2, varscan2
- C10orf71 | c.732C>T p.T244= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs368739800; called by muse, mutect2, varscan2
- CEACAM21 | c.165G>A p.V55= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV51814977, COSV99494891; called by muse, mutect2, varscan2
- COL9A1 | c.759T>C p.H253= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1264012472, COSV57895401; called by muse, mutect2, varscan2
- CTCF | c.1689A>G p.T563= | Silent (SNP) | VAF 102/379 reads (27%) | catalogued as rs1434608955, COSV50469536, COSV50540839; called by muse, mutect2, varscan2
- CTNNA2 | c.183T>G p.A61= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV63609377; called by muse, mutect2, varscan2
- CTNNA2 | c.1692G>A p.G564= | Silent (SNP) | VAF 17/318 reads (5%) | catalogued as COSV58188130; called by muse, mutect2
- DVL3 | c.1584G>A p.G528= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53048095; called by muse, mutect2, varscan2
- IDO2 | c.405G>T p.L135= (on ENST00000389060; = p.L148= on NM_194294.2) | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV58430586; called by muse, mutect2, varscan2
- KIAA0408 | c.303G>C p.L101= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV100846977; called by muse, mutect2, varscan2
- KIZ | c.1185G>A p.Q395= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55689109; called by muse, mutect2, varscan2
- KRT8 | c.219G>A p.L73= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1036555640, COSV53179666; called by muse, mutect2
- LDHAL6B | c.438T>A p.G146= | Silent (SNP) | VAF 63/260 reads (24%) | catalogued as COSV55697626; called by muse, mutect2, varscan2
- LRP2 | c.2982C>T p.F994= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV55579540; called by muse, mutect2, varscan2
- MAPK8IP1 | c.580C>A p.R194= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as COSV53799518, COSV53800248; called by muse, mutect2
- NCBP3 | c.1515T>C p.F505= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV50112827; called by muse, mutect2, varscan2
- NCOA1 | c.1458C>T p.F486= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV56054837; called by muse, mutect2, varscan2
- NCOA4 | c.519A>T p.A173= | Silent (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- NHS | c.4419C>A p.P1473= | Silent (SNP) | VAF 60/310 reads (19%) | catalogued as COSV66284770; called by muse, mutect2, varscan2
- NRXN1 | c.1923G>T p.V641= | Silent (SNP) | VAF 103/406 reads (25%) | catalogued as COSV58434250, COSV58502302; called by muse, mutect2, varscan2
- ONECUT1 | c.559C>T p.L187= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV59951367; called by muse, mutect2, varscan2
- PLPPR4 | c.2028G>C p.L676= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV64568009; called by muse, mutect2, varscan2
- PROKR2 | c.816G>A p.K272= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs367826294, COSV99027846; called by muse, mutect2, varscan2
- RYR2 | c.8094A>G p.E2698= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV63721101; called by muse, mutect2, varscan2
- SEMA5B | c.3183C>T p.H1061= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV52110923; called by muse, mutect2, varscan2
- SIGLEC7 | c.591C>A p.T197= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV58318385, COSV99978469; called by muse, mutect2
- SLC39A10 | c.1062C>T p.P354= | Silent (SNP) | VAF 75/330 reads (23%) | catalogued as COSV62770120; called by muse, mutect2, varscan2
- SLCO1C1 | c.1617A>G p.G539= | Silent (SNP) | VAF 70/265 reads (26%) | catalogued as COSV56881869; called by muse, mutect2, varscan2
- SLITRK3 | c.2901C>G p.L967= | Silent (SNP) | VAF 79/330 reads (24%) | catalogued as COSV53851275, COSV53854620, COSV99580203; called by muse, mutect2, varscan2
- SMARCC2 | c.2370C>G p.T790= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as COSV57226213; called by muse, mutect2, varscan2
- STAB2 | c.2883C>A p.T961= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as COSV101185667, COSV66335582, COSV66345583; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2019C>T p.H673= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs747923465, COSV99304956; called by muse, mutect2, varscan2
- USP9X | c.5955A>T p.S1985= | Silent (SNP) | VAF 76/415 reads (18%) | catalogued as COSV61076759; called by muse, mutect2, varscan2
- VPS50 | c.2763C>T p.I921= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59923944; called by muse, mutect2, varscan2
- ZNF354C | c.13C>T p.L5= | Silent (SNP) | VAF 36/275 reads (13%) | catalogued as rs149113509; called by muse, mutect2, varscan2
- MORF4 | n.956T>A | RNA (SNP) | VAF 112/178 reads (63%) | called by muse, mutect2, varscan2
- ZNF493 | c.-112T>A | 5'UTR (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100828770; called by muse, mutect2
